Somatic mutation profile of tumor specimen MMRF_1569_1_BM_CD138pos (aliquot MMRF_1569_1_BM_CD138pos_T2_KBS5U_L05370) from MMRF case MMRF_1569, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.5 years (25,744 days).
Specimen MMRF_1569_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 196a9be0-2f37-4ce6-b7d9-db317abca369.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1569_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1569_1_PB_Whole_C3_KBS5U_L05355; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/474e7500-0b31-4206-ab02-4c73fe46b9c3

The open-access MAF lists 95 somatic variants for this specimen: 44 protein-altering or splice-affecting, 6 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 26, Intron 10, Silent 6, 5'Flank 3, RNA 2, Splice Site 2, 3'Flank 2, 5'UTR 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRE2 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs564713952, COSV59694652; called by muse, mutect2, varscan2
- ARHGAP42 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs543217961; called by muse, varscan2
- CHRNA1 | c.1291A>G p.M431V (on ENST00000261007 / NM_001039523.3; = p.M406V on NM_000079.4) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs376515416; called by muse, mutect2, varscan2
- DCAF12L2 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV63584200; called by muse, mutect2
- DSCAML1 | c.2761G>A p.D921N (on ENST00000321322; = p.D861N on NM_020693.4) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV58396291; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs138696988; called by muse, mutect2, varscan2
- EFR3A | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as rs1462655161; called by muse, mutect2, varscan2
- FAXDC2 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV58172196; called by muse, mutect2, varscan2
- GRIK1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs756832977, COSV58713145; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as rs184904469; called by muse, varscan2
- IGHV2-70 | c.238T>G p.Y80D | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs374660856; called by muse, varscan2
- IGHV2-70 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs181122105; called by muse, varscan2
- IGHV2-70D | c.127T>G p.F43V | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1369575117; called by muse, mutect2
- JUNB | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 196/413 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.705); catalogued as rs1245715051; called by muse, mutect2, varscan2
- KCTD20 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.653); catalogued as rs748850127; called by muse, mutect2, varscan2
- KRT75 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs779742513, COSV52871179, COSV52873294; called by muse, mutect2, varscan2
- PCDHA7 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV65343014; called by muse, mutect2, varscan2
- PGR | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs747217871; called by muse, mutect2, varscan2
- PITPNM2 | c.3688G>A p.V1230M | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1402049148, COSV54906780; called by muse, mutect2, varscan2
- POFUT1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.97); catalogued as rs778630208; called by muse, mutect2, varscan2
- SLC5A4 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs929227694, COSV56668070; called by muse, mutect2, varscan2
- A2ML1 | c.1080+1G>C p.X360_splice | Splice Site (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4993T>C p.S1665P | Missense Mutation (SNP) | VAF 96/158 reads (61%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBEC3D | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF6 | c.1769G>C p.S590T | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ARRDC2 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ATP13A3 | c.3008C>A p.S1003Y | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- E2F7 | c.2335G>A p.G779R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GADL1 | c.429-5_429-2del p.X143_splice | Splice Site (DEL) | VAF 28/123 reads (23%) | called by pindel, varscan2
- GAST | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- HSP90B1 | c.107del p.G36Vfs*13 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.52); PolyPhen benign (0.087); called by muse, mutect2
- KIAA1549L | c.4335T>A p.H1445Q (on ENST00000321505; = p.H1742Q on NM_012194.3) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- LILRB3 | c.1489C>T p.P497S (on ENST00000346401; = p.P485S on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- MUC16 | c.1835C>T p.T612I | Missense Mutation (SNP) | VAF 125/239 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- MYL4 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- OTOP3 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- RIN3 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIPK2 | c.587A>T p.E196V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RXRB | c.56G>C p.C19S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- SEC23A | c.234_270del p.Y78* | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel
- SERPINA2 | c.497A>T p.H166L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TRIM5 | c.1435C>G p.P479A | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- ANKRD24 | c.267G>T p.A89= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- DLGAP1 | c.1113G>A p.A371= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs200329557; called by muse, mutect2
- LZTS1 | c.1113C>T p.T371= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- PCDH19 | c.636C>T p.D212= | Silent (SNP) | VAF 79/88 reads (90%) | catalogued as COSV55265938; called by muse, mutect2, varscan2
- RFX2 | c.1578G>A p.A526= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs752822956, COSV57945182; called by muse, mutect2, varscan2
- STARD8 | c.1389T>C p.A463= | Silent (SNP) | VAF 45/48 reads (94%) | called by muse, mutect2, varscan2
- ABCB5 | c.1707+456C>T | Intron (SNP) | VAF 82/312 reads (26%) | catalogued as rs576948289, COSV99329295; called by muse, mutect2, varscan2
- ABCC5 | c.*71G>A | 3'UTR (SNP) | VAF 136/203 reads (67%) | catalogued as rs944287777, COSV55590219; called by muse, mutect2, varscan2
- ABLIM3 | c.*217G>T | 3'UTR (SNP) | VAF 89/144 reads (62%) | called by muse, mutect2, varscan2
- ACRP1 | n.243G>C | RNA (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- ADAM3A | n.1940T>G | RNA (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- ALPG | c.*358C>T | 3'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- ATP10B | c.*1597G>C | 3'UTR (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- BEST2 | c.*310G>A | 3'UTR (SNP) | VAF 85/167 reads (51%) | catalogued as rs1308561987; called by muse, mutect2, varscan2
- C7orf61 | c.-67A>C | 5'UTR (SNP) | VAF 8/36 reads (22%) | catalogued as rs879202625; called by muse, mutect2
- CCDC15 | c.*518T>G | 3'UTR (SNP) | VAF 6/159 reads (4%) | called by muse, mutect2
- DSC2 | c.*877G>A | 3'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- EPHA5 | c.*3366C>T | 3'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- ERGIC1 | c.156-4353G>A | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- ERGIC2 | c.*735A>G | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- FNBP1 | c.*2764A>C | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- FNBP1 | c.*2563T>C | 3'UTR (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- FNBP1 | c.*2562T>C | 3'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- FNBP1 | c.*2462A>G | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- IGFN1 | c.*66G>A | 3'UTR (SNP) | VAF 103/211 reads (49%) | called by muse, mutect2, varscan2
- KIF2A | chr5:62385937 T>C | 3'Flank (SNP) | VAF 18/78 reads (23%) | catalogued as rs1170285116; called by muse, mutect2, varscan2
- LOX | c.*3103T>A | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- MCTP2 | c.970-1811G>A | Intron (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- MEF2C | c.-139-171T>A | Intron (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- MROH2B | c.1502-31A>T | Intron (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- PCSK9 | c.*183T>A | 3'UTR (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- PDLIM4 | c.327+43C>T | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- PIDD1 | c.296-45T>C | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- RIMS2 | c.*1003T>C | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- RPS23 | c.*444G>A | 3'UTR (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+763G>C | Intron (SNP) | VAF 53/121 reads (44%) | catalogued as COSV73912641; called by muse, mutect2, varscan2
- SCAMP2 | c.*1056A>G | 3'UTR (SNP) | VAF 81/173 reads (47%) | called by muse, mutect2, varscan2
- SEC62 | c.*2981G>A | 3'UTR (SNP) | VAF 34/95 reads (36%) | catalogued as rs980304032; called by muse, mutect2, varscan2
- SH3PXD2B | c.*1372G>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs1193980328; called by muse, mutect2, varscan2
- SLC38A7 | c.*965C>A | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- SLC39A9 | c.-372C>T | 5'UTR (SNP) | VAF 88/169 reads (52%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20315421 G>A | 3'Flank (SNP) | VAF 31/63 reads (49%) | catalogued as rs189773724; called by muse, mutect2, varscan2
- SSNA1 | c.*30T>G | 3'UTR (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- TBC1D10C | c.583-103G>A | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- TBL2 | chr7:73578585 C>T | 5'Flank (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- THRB | c.*4152T>A | 3'UTR (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975348 G>C | 5'Flank (SNP) | VAF 63/67 reads (94%) | called by muse, mutect2, varscan2
- UBXN10 | c.*408C>A | 3'UTR (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- UMODL1 | c.1299+360C>T | Intron (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- USF3 | c.*5450T>A | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- VPS35L | chr16:19555282 G>A | 5'Flank (SNP) | VAF 5/17 reads (29%) | called by muse, varscan2
